Gene-level copy-number profile of tumor specimen ALCH-AEF0-TTP1-A from ALCHEMIST case ALCH-AEF0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.2 years (29,669 days).
Specimen ALCH-AEF0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b953a3e3-8689-4c9f-aacd-2853ca1ba23a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEF0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/bf830098-e51e-4f9e-beba-31d365a2d2ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 4,813; copy number 2: 48,634; copy number 3: 3,920; copy number 4: 653; copy number 5: 137; copy number 6: 122; copy number 7: 21; copy number 8: 9; copy number 33: 3.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,409,009–22,128,103, 74 genes (broad region; genes not listed).
- chr9:41,340,823–41,355,538, 1 gene: CDRT15P6.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 292 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 33: AC239859.5, RNA5SP533, AC239859.3.
- chr16:1,333,638–1,918,415, 48 genes, copy number 5: BAIAP3, TSR3, GNPTG, AL031709.1, UNKL, AL032819.1, C16orf91, PERCC1, CCDC154, AL032819.2, CLCN7, AL031600.3, AL031600.1, AL031600.2, RPS3AP2, PTX4, TELO2, IFT140, AL031705.1, TMEM204, AL031719.1, AL031719.2, Z97633.1, AL133297.1, AL133297.2, CRAMP1, Z97652.1, AL031708.1, JPT2, AL031009.1, MAPK8IP3, AL031710.2, AL031710.1, MIR3177, AL031717.1, NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS, HAGH, FAHD1, MEIOB, AL031722.1, LINC00254, LINC02124, HS3ST6.
- chr16:4,693,694–5,235,822, 27 genes, copy number 6: NUDT16L1, ANKS3, AC020663.1, C16orf71, ZNF500, Metazoa_SRP, SEPTIN12, AC020663.4, SMIM22, AC020663.2, ROGDI, GLYR1, AC020663.3, UBN1, PPL, SEC14L5, NAGPA-AS1, NAGPA, ALG1, C16orf89, AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–5,366,688, 4 genes, copy number 6 (within-gene range 3–6): AC074051.2, RPS3AP48, SNRPCP20, NPM1P3.
- chr16:10,326,434–11,349,321, 43 genes, copy number 6: ATF7IP2, AC131649.1, AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1, MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24, NUBP1, TVP23A, AC133065.2, AC133065.1, CIITA, DEXI, AC133065.3, CLEC16A, RPL7P46, AC007014.2, AC007014.1, AC007220.2, AC007220.1, HNRNPCP4, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2.
- chr16:11,750,586–11,797,258, 1 gene, copy number 6 (within-gene range 4–6): ZC3H7A.
- chr16:11,797,468–12,803,887, 29 genes, copy number 6: AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2.
- chr16:15,865,719–16,398,594, 25 genes, copy number 5: CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1, RPL17P40, ABCC6, AC136624.1, NOMO3, AC136624.3, AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1.
- chr16:23,017,723–23,064,173, 2 genes, copy number 5 (within-gene range 2–5): AC127459.2, AC127459.1.
- chr16:23,061,767–23,062,232, 1 gene, copy number 5 (within-gene range 2–5): AC127459.3.
- chr20:35,433,029–36,088,192, 34 genes, copy number 5: GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2.
- chr20:38,127,385–38,166,578, 1 gene, copy number 6 (within-gene range 3–6): TGM2.
- chr20:38,601,934–38,651,035, 2 genes, copy number 7: ARHGAP40, AL035419.1.
- chr20:53,255,979–55,684,915, 23 genes, copy number 5–8 (within-gene range 4–8): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr20:56,358,974–56,392,337, 2 genes, copy number 5: FAM210B, AURKA.
- chr20:56,468,585–57,163,775, 17 genes, copy number 6: RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3.
- chr20:58,817,132–58,911,192, 12 genes, copy number 7: AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2.
- chr20:59,113,224–59,516,039, 7 genes, copy number 7: MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1.
- chr20:63,520,765–63,698,684, 11 genes, copy number 5 (within-gene range 4–5): PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B.

Autosomal genes at a single copy (total copy number 1): 4,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
